MMRF case MMRF_2505 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e8f5b7f9-183e-44ee-b659-bddf927d706a

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.6 years (25,054 days); ISS stage: II; Days to last known disease status: 703 days (1.9 years); Days to last follow up: 703 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6: M Protein 6.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.23 mg/dL; Immunoglobulin G 87 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 4.67 µg/mL; Hemoglobin 5.08 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.48 mmol/L; Albumin 26 g/L; Total Protein 12.8 g/dL; Glucose 6.49 mmol/L; C-Reactive Protein 13 mg/dL.
- Day 104: M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.22 mg/dL; Hemoglobin 5.95 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.13 mmol/L; Albumin 28 g/L; Total Protein 7.4 g/dL; Glucose 4.29 mmol/L.
- Day 188: M Protein 0.2 g/dL; Hemoglobin 6.57 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 12.6 mmol/L.
- Day 272: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Hemoglobin 5.89 mmol/L; Leukocytes 3.74 ×10⁹/L; Absolute Neutrophil 3.18 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 8.64 mmol/L.
- Day 334: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Hemoglobin 5.83 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 8.2 mmol/L.
- Day 432: Hemoglobin 5.77 mmol/L; Leukocytes 2.87 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.03 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 12.9 mmol/L.
- Day 535: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Hemoglobin 5.46 mmol/L; Leukocytes 3.04 ×10⁹/L; Absolute Neutrophil 1.64 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 160 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 5.89 mmol/L.
- Day 623: M Protein 1.2 g/dL; Immunoglobulin G 21 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.6 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.92 ×10⁹/L; Absolute Neutrophil 2.76 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 8.4 g/dL; Glucose 5.78 mmol/L.
- Day 703: M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Beta 2 Microglobulin 5.91 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 3.87 ×10⁹/L; Absolute Neutrophil 2.16 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 31 g/L; Total Protein 8 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -6: Weight: 88 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2505_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2505_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
